Somatic mutation profile of tumor specimen c2c53076-b5db-4b7d-983c-a35740 (aliquot c2c53076-b5db-4b7d-983c-a35740_D6) from CPTAC case 09CO006, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen c2c53076-b5db-4b7d-983c-a35740: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0677f5b4-0167-4fba-a168-aec8165a47e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen bcf6d821-c2f1-4d84-81e0-f41b45 (Blood Derived Normal), aliquot bcf6d821-c2f1-4d84-81e0-f41b45_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c1e56c7-5463-44fe-95e3-1178c581be7f

The open-access MAF lists 109 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 26, Intron 7, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 38/180 reads (21%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 76/425 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 61/271 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VWF | c.7732C>T p.R2578C | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs369970893, COSV54623139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACOT11 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.484); catalogued as rs1278466398, COSV59351102; called by muse, mutect2, varscan2
- ADGRD1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as rs749836301, COSV55438330; called by muse, mutect2, varscan2
- ANGPTL2 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs769982032; called by muse, mutect2, varscan2
- ARHGAP24 | c.1180G>A p.A394T (on ENST00000395184 / NM_001025616.3; = p.A301T on NM_031305.3) | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs952136110; called by muse, mutect2, varscan2
- CACNA1H | c.6544C>T p.R2182C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1244507563, COSV52356342; called by muse, varscan2
- CACNA1I | c.1904G>A p.G635D | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs1474052770; called by muse, mutect2, varscan2
- CCDC166 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); catalogued as rs576059302; called by muse, mutect2, varscan2
- CDH24 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99943645; called by muse, mutect2, varscan2
- CELSR1 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922927841; called by muse, mutect2, varscan2
- CHD4 | c.1747C>T p.R583* (on ENST00000357008 / NM_001363606.2; = p.R596* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 124/454 reads (27%) | catalogued as COSV58910078; called by muse, mutect2, varscan2
- CILP | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs527396607, COSV56023574; called by muse, mutect2, varscan2
- COL3A1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 70/434 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs760324242, COSV58584331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP3 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs200655168; called by muse, mutect2, varscan2
- EMILIN3 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs139057198; called by muse, mutect2, varscan2
- GGTLC2 | c.360+4C>T | Splice Region (SNP) | VAF 112/539 reads (21%) | catalogued as rs755813700; called by muse, mutect2, varscan2
- GRIA2 | c.2464G>A p.G822R | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52397066; called by muse, mutect2, varscan2
- GRM2 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs61729077; called by muse, mutect2, varscan2
- IFI16 | c.2344G>T p.D782Y (on ENST00000295809 / NM_001364867.2; = p.D726Y on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1297756816; called by muse, mutect2, varscan2
- IQSEC3 | c.1384G>A p.G462R (on ENST00000538872 / NM_001170738.2; = p.G159R on NM_015232.1) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782335400, COSV58291376; called by muse, mutect2
- KCNA3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs543492829, COSV63901275, COSV63902360; called by muse, mutect2, varscan2
- KMT2B | c.6095C>T p.S2032F | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as rs527676065; called by muse, mutect2, varscan2
- NOD1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 150/403 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs570225517, COSV56111447; called by muse, varscan2
- NRXN1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs748684256, COSV68017694; called by muse, mutect2, varscan2
- OR2A1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 206/2068 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs750474119, COSV68822756; called by mutect2, varscan2
- OTUD7A | c.1724G>A p.R575H (on ENST00000307050 / NM_001382637.1; = p.R568H on NM_130901.3) | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.897); catalogued as rs776292350, COSV61036573; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHGA5 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 106/551 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs776618534, COSV53998693; called by muse, mutect2, varscan2
- RBMXL2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 69/376 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV60979613; called by muse, mutect2, varscan2
- SART1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs377371371, COSV100409011; called by muse, mutect2, varscan2
- SETDB1 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 16/405 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54979818; called by muse, mutect2
- SYCP2 | c.1799C>A p.P600H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100697866; called by muse, mutect2, varscan2
- TCF7L2 | c.1142A>C p.N381T (on ENST00000355995 / NM_001367943.1; = p.N358T on NM_030756.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99526922; called by muse, mutect2, varscan2
- TDRD1 | c.3251T>C p.V1084A | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52589748; called by muse, mutect2, varscan2
- TEAD1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100531765; called by muse, mutect2, varscan2
- THBS2 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 116/518 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.359); catalogued as rs558980944, COSV64681525, COSV64681997; called by muse, mutect2, varscan2
- TIE1 | c.3260G>A p.R1087H | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs146799667; called by muse, mutect2, varscan2
- TNR | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 87/450 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs138654492; called by muse, mutect2, varscan2
- VPS45 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs782426640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WARS1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs772843016, COSV59924170; called by muse, mutect2, varscan2
- APC | c.2524del p.D842Ifs*19 | Frame Shift Del (DEL) | VAF 77/399 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP30 | c.2697G>T p.E899D (on ENST00000368013 / NM_001025598.2; = p.E688D on NM_181720.3) | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by mutect2, varscan2
- ARHGEF7 | c.1638T>G p.F546L (on ENST00000375741 / NM_001113511.2; = p.F368L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- C12orf65 | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC85A | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CPT1B | c.1376del p.L459Pfs*129 | Frame Shift Del (DEL) | VAF 31/152 reads (20%) | called by mutect2, pindel, varscan2
- DMAP1 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DMRTB1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERC1 | c.2755C>T p.H919Y (on ENST00000360905 / NM_178040.4; = p.H891Y on NM_178039.4) | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- FADS3 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FKRP | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR89A | c.1167G>A p.M389I | Missense Mutation (SNP) | VAF 100/500 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- GUCY1A1 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- H2BC12 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HTRA3 | c.153C>A p.C51* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- IKZF5 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK1 | c.2846A>G p.D949G | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NEO1 | c.1672A>G p.T558A | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NUP210 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.006); called by mutect2, varscan2
- OR9Q1 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- OVOL3 | c.568G>A p.V190M (on ENST00000585332; = p.V166M on NM_001302757.1) | Missense Mutation (SNP) | VAF 68/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PABPC1 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- SEMA4D | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SGSH | c.482_484del p.K161_F162delinsI | In Frame Del (DEL) | VAF 97/426 reads (23%) | called by mutect2, pindel, varscan2
- SOX9 | c.1511dup p.Q505Tfs*73 | Frame Shift Ins (INS) | VAF 45/271 reads (17%) | called by mutect2, pindel, varscan2
- TGIF1 | c.184-2A>G p.X62_splice (on ENST00000330513 / NM_001374396.1; = p.X82_splice on NM_003244.4) | Splice Site (SNP) | VAF 62/304 reads (20%) | called by muse, mutect2, varscan2
- TSEN15 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TTN | c.57973C>A p.R19325S (on ENST00000591111; = p.R11901S on NM_003319.4) | Missense Mutation (SNP) | VAF 183/475 reads (39%) | PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ZNF318 | c.5068A>G p.T1690A | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.527G>C p.S176T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ABI3 | c.585G>A p.P195= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as rs755161200; called by muse, mutect2, varscan2
- CARD9 | c.75C>T p.I25= | Silent (SNP) | VAF 70/358 reads (20%) | catalogued as rs139436668; called by muse, mutect2, varscan2
- CDK5R1 | c.594G>A p.P198= | Silent (SNP) | VAF 127/613 reads (21%) | catalogued as rs757514550; called by muse, mutect2, varscan2
- CHD5 | c.3042C>T p.Y1014= | Silent (SNP) | VAF 43/202 reads (21%) | catalogued as rs761251450; called by muse, mutect2, varscan2
- CHST12 | c.507C>T p.Y169= | Silent (SNP) | VAF 61/314 reads (19%) | catalogued as rs1476348634, COSV51676895; called by muse, mutect2, varscan2
- CHST13 | c.663C>T p.H221= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, varscan2
- DOCK11 | c.4623A>G p.L1541= | Silent (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- ENTPD3 | c.639A>G p.E213= | Silent (SNP) | VAF 96/313 reads (31%) | called by muse, mutect2, varscan2
- ESPN | c.2001G>T p.P667= | Silent (SNP) | VAF 152/666 reads (23%) | called by muse, varscan2
- FAT4 | c.2958C>T p.V986= | Silent (SNP) | VAF 71/404 reads (18%) | catalogued as COSV101272318; called by muse, mutect2, varscan2
- FCGBP | c.5616C>T p.Y1872= | Silent (SNP) | VAF 67/884 reads (8%) | catalogued as rs1388553185; called by muse, mutect2
- FXYD2 | c.15G>T p.S5= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as COSV99411335; called by muse, mutect2, varscan2
- GRIN2C | c.1623C>T p.T541= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs145450475; called by muse, varscan2
- HSFX2 | c.147C>T p.D49= | Silent (SNP) | VAF 66/150 reads (44%) | called by mutect2, varscan2
- LRIG1 | c.1227G>A p.E409= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as rs754870091; called by muse, mutect2, varscan2
- MORF4L1 | c.912A>G p.R304= (on ENST00000331268 / NM_206839.2; = p.R265= on NM_006791.4) | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- MUC5B | c.13464C>T p.P4488= | Silent (SNP) | VAF 57/558 reads (10%) | called by muse, mutect2, varscan2
- MYLK | c.3084C>T p.N1028= | Silent (SNP) | VAF 50/214 reads (23%) | catalogued as rs751399308, COSV60604998; called by muse, mutect2, varscan2
- NOBOX | c.660G>A p.P220= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as rs1457254748, COSV56198292; called by muse, mutect2, varscan2
- PHGDH | c.1407G>A p.R469= | Silent (SNP) | VAF 84/505 reads (17%) | called by muse, mutect2, varscan2
- PIFO | c.423G>A p.P141= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs548343385; called by muse, mutect2, varscan2
- PXDNL | c.2958C>T p.S986= | Silent (SNP) | VAF 60/311 reads (19%) | catalogued as rs952661664, COSV62477568; called by muse, mutect2, varscan2
- TCAIM | c.1113T>G p.L371= | Silent (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- TIAM1 | c.1680C>T p.L560= | Silent (SNP) | VAF 84/417 reads (20%) | catalogued as rs868585803, COSV99737999; called by muse, mutect2, varscan2
- TLE1 | c.1782C>T p.S594= | Silent (SNP) | VAF 55/271 reads (20%) | catalogued as rs773935551; called by muse, mutect2, varscan2
- TUBA3C | c.1266C>T p.R422= | Silent (SNP) | VAF 26/211 reads (12%) | catalogued as rs141224369; called by muse, mutect2, varscan2
- CARTPT | c.*46C>T | 3'UTR (SNP) | VAF 43/179 reads (24%) | catalogued as rs183782239; called by muse, mutect2, varscan2
- CSMD2 | c.6863-5281G>A | Intron (SNP) | VAF 37/176 reads (21%) | catalogued as rs777517487; called by muse, mutect2, varscan2
- FGF14 | c.608-21C>T | Intron (SNP) | VAF 54/351 reads (15%) | catalogued as rs201498757; called by muse, mutect2, varscan2
- GIGYF2 | c.533-10738G>T | Intron (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- MRPS27 | c.694+32T>G | Intron (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- PEG10 | c.*38C>T | 3'UTR (SNP) | VAF 76/434 reads (18%) | called by muse, mutect2, varscan2
- RGS6 | c.1369-11922T>G | Intron (SNP) | VAF 37/197 reads (19%) | called by muse, mutect2, varscan2
- RIMS1 | c.3398+16T>A | Intron (SNP) | VAF 104/471 reads (22%) | catalogued as rs763102599; called by muse, mutect2, varscan2
- SAFB | c.2552-36G>T | Intron (SNP) | VAF 26/104 reads (25%) | catalogued as rs369017493; called by muse, mutect2, varscan2
- UNG | c.-51A>G | 5'UTR (SNP) | VAF 32/158 reads (20%) | catalogued as rs375712849; called by muse, mutect2, varscan2
